Somatic mutation profile of tumor specimen TCGA-32-2616-01A (aliquot TCGA-32-2616-01A-01D-1495-08) from TCGA case TCGA-32-2616, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.7 years (17,781 days).
Specimen TCGA-32-2616-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe3892db-076d-4223-b60e-5613e10bdd7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-2616-10A (Blood Derived Normal), aliquot TCGA-32-2616-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f4c30a2-cc49-4993-b861-8a1c3c38020f

The open-access MAF lists 1,167 somatic variants for this specimen: 817 protein-altering or splice-affecting, 333 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 750, Silent 333, Nonsense Mutation 49, Splice Region 10, Intron 10, Frame Shift Ins 4, Splice Site 3, RNA 3, 3'UTR 2, 5'UTR 2, Frame Shift Del 1.

Variants (750 of 1,167; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN3 | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863224957, CM980303, COSV100520606; ClinVar: pathogenic; called by muse, mutect2
- COL11A2 | c.4438G>A p.G1480R (on ENST00000341947 / NM_080680.3; = p.G1373R on NM_080679.2) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172866556, COSV100554453; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1555198522, COSV56467834; ClinVar: likely pathogenic; called by muse, mutect2
- MYO7A | c.6487G>A p.G2163S | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs747656448, CM990906, COSV60020751; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 92/218 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1064793663, COSV55877982, COSV55886419, COSV56022812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as rs587782350, CM991083, COSV64291511, COSV64305247; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- RB1 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 32/45 reads (71%) | hotspot (GDC flag); catalogued as rs121913303, CM961229, COSV57297124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.4534C>T p.R1512W (on ENST00000333535 / NM_198056.3; = p.R1511W on NM_000335.5) | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137854602, CM994138, COSV61119646; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 27/52 reads (52%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TWNK | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 111/296 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753386843, COSV100147058, COSV100147148; ClinVar: likely pathogenic; called by muse, mutect2
- ABCA7 | c.4477G>A p.A1493T | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs201941781; called by muse, mutect2, varscan2
- ABCB4 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs778380044, COSV99711140; called by muse, mutect2
- ABCC4 | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1049918565, COSV100972742; called by muse, mutect2, varscan2
- ABCC5 | c.3448G>A p.A1150T | Missense Mutation (SNP) | VAF 135/344 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV99657470; called by muse, varscan2
- ABCD1 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs782252768, COSV99497874; called by muse, mutect2
- ABCG4 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100266980; called by muse, mutect2, varscan2
- ABHD11 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as rs782669772, COSV56105668; called by muse, mutect2, varscan2
- AC092143.1 | c.1141G>A p.G381S | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV100206043; called by muse, mutect2, varscan2
- ACACB | c.3154C>T p.R1052C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as rs777435824, COSV100623248; called by muse, mutect2, varscan2
- ACACB | c.3596C>T p.S1199L | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs763388361, COSV58130479; called by muse, mutect2, varscan2
- ACAN | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764993901, COSV100719103; called by muse, mutect2, varscan2
- ACO2 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 165/444 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.579); catalogued as rs200327053, COSV53444530; called by muse, mutect2, varscan2
- ACTL8 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs759294923, COSV100958778; called by muse, mutect2, varscan2
- ADAMTS10 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV99547352; called by muse, mutect2, varscan2
- ADAMTS14 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as rs202183313; called by muse, mutect2, varscan2
- ADAMTS19 | c.3199G>A p.V1067I | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs767110495, COSV99180331; called by muse, mutect2
- ADAMTS3 | c.3358C>T p.P1120S | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV99711897; called by muse, mutect2, varscan2
- ADAMTS3 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 121/310 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as rs183558490, COSV99711898; called by muse, mutect2, varscan2
- ADAMTS9 | c.3968G>A p.R1323H | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs755956495, COSV55781275; called by muse, mutect2, varscan2
- ADCY1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52033824; called by muse, mutect2, varscan2
- ADCY10 | c.3961C>T p.R1321* | Nonsense Mutation (SNP) | VAF 99/241 reads (41%) | catalogued as COSV100897049; called by muse, mutect2, varscan2
- ADCY3 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99569016; called by muse, mutect2
- ADCY7 | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs770623244, COSV99576206; called by muse, mutect2, varscan2
- ADGRB1 | c.3961G>A p.G1321S | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.174); catalogued as rs774828542, COSV60091234; called by muse, mutect2, varscan2
- AGAP3 | c.1463G>A p.R488H (on ENST00000622464; = p.R524H on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs925378481, COSV68242968; called by muse, mutect2, varscan2
- AGBL4 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as rs758153531, COSV65761577; called by muse, varscan2
- AGRN | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1008012998, COSV101039047; called by muse, mutect2, varscan2
- AGXT2 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746146731, COSV51483571; called by muse, mutect2, varscan2
- AHCTF1 | c.6760C>T p.R2254W (on ENST00000366508; = p.R2228W on NM_015446.5) | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs758346249, COSV58248341; called by muse, mutect2, varscan2
- AHCTF1 | c.2987G>A p.R996H (on ENST00000366508; = p.R970H on NM_015446.5) | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs543659382, COSV58251936; called by muse, mutect2, varscan2
- AHCYL1 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs546281118, COSV63208326; called by muse, mutect2, varscan2
- AHDC1 | c.1642G>A p.G548S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99899158; called by muse, mutect2, varscan2
- AICDA | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV57564262; called by muse, mutect2, varscan2
- AKR1B10 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 100/461 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs372587864; called by muse, mutect2, varscan2
- AKR1C2 | c.87T>C p.V29= | Splice Region (SNP) | VAF 11/177 reads (6%) | catalogued as COSV101060521; called by muse, mutect2
- ALDH2 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs534531260, COSV55666053; called by muse, mutect2, varscan2
- ALDH3B1 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.087); catalogued as rs1271627881, COSV99142045; called by muse, mutect2, varscan2
- ALPK3 | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV99361526, COSV99361840; called by muse, mutect2, varscan2
- ALX1 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100374547; called by muse, mutect2, varscan2
- ALX4 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763248407, COSV61326642; called by muse, mutect2, varscan2
- ALX4 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs747909089, COSV61327684; called by muse, mutect2, varscan2
- AMFR | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs142836436; called by muse, mutect2, varscan2
- AMN1 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1396798900, COSV99861668; called by muse, mutect2, varscan2
- ANK1 | c.3046G>A p.V1016M | Missense Mutation (SNP) | VAF 103/248 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs779150672, COSV99226606; called by muse, mutect2, varscan2
- ANKMY1 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as rs201824658; called by muse, mutect2, varscan2
- ANKRD11 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 84/197 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs773132293, COSV99970420; called by muse, mutect2, varscan2
- ANKRD13B | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs775947551, COSV101198903; called by muse, mutect2, varscan2
- ANKRD55 | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.974); catalogued as rs770473679, COSV100591580; called by muse, mutect2, varscan2
- AP002512.3 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs777835699, COSV54405581; called by muse, mutect2, varscan2
- APOL5 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs750413929, COSV50768088; called by muse, mutect2, varscan2
- ARFGEF3 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs750887978, COSV52459247, COSV99294542; called by muse, mutect2, varscan2
- ARFGEF3 | c.2221G>A p.A741T | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs768812205, COSV99294545; called by muse, mutect2, varscan2
- ARFGEF3 | c.6463G>A p.D2155N | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.734); catalogued as rs373010266; called by muse, mutect2, varscan2
- ARHGAP22 | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752933087, COSV50977793; called by muse, mutect2, varscan2
- ARHGAP27 | c.2257C>T p.R753C (on ENST00000428638 / NM_001282290.1; = p.R412C on NM_199282.3) | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1363116633, COSV100976607; called by muse, mutect2, varscan2
- ARHGAP9 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs145403284; called by muse, mutect2, varscan2
- ARHGEF11 | c.4385C>T p.T1462M | Missense Mutation (SNP) | VAF 97/263 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs747398529, COSV100168889; called by muse, mutect2, varscan2
- ARHGEF11 | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59352457; called by muse, mutect2, varscan2
- ARHGEF11 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs200051467, COSV100168895; called by muse, mutect2, varscan2
- ARMC2 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367783758; called by muse, mutect2, varscan2
- ARSI | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs776520005, COSV60817216; called by muse, mutect2, varscan2
- ASAP3 | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371915285; called by muse, mutect2
- ASCC3 | c.6134C>T p.S2045L | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs998057299, COSV100976845; called by muse, mutect2, varscan2
- ASTN1 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.197); catalogued as COSV99922831; called by muse, mutect2, varscan2
- ATF6B | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs769425534, COSV100916850; called by muse, mutect2, varscan2
- ATF7IP | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs767883210, COSV53776955, COSV99661480; called by muse, mutect2, varscan2
- ATG101 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs376747724, COSV61084830; called by muse, mutect2, varscan2
- ATL1 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 126/360 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs1278783412, COSV63296335; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATN1 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as rs781797208, COSV63112473; called by muse, mutect2, varscan2
- ATP11A | c.3268G>A p.D1090N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1411005250, COSV52110812; called by muse, mutect2, varscan2
- ATP2B3 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as rs943411634, COSV54852904; called by muse, mutect2, varscan2
- ATP2B3 | c.2767C>T p.R923C | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs141643926, COSV99684303, COSV99685610; called by muse, mutect2, varscan2
- ATP6V0A2 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100377134; called by muse, mutect2, varscan2
- ATP9B | c.2425C>T p.R809* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as rs147932692; called by muse, mutect2, varscan2
- ATRNL1 | c.3016T>C p.W1006R | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100372579; called by muse, mutect2, varscan2
- ATXN1 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs760989672, COSV55213469; called by muse, mutect2, varscan2
- ATXN10 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs542453268, COSV99426676; called by muse, mutect2, varscan2
- BAZ2A | c.5249C>T p.S1750L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs760456958, COSV99467484; called by muse, mutect2, varscan2
- BCAR3 | c.922C>A p.L308I | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV53080429; called by muse, mutect2, varscan2
- BCL11A | c.1724C>T p.P575L (on ENST00000335712 / NM_001365609.1; = p.P609L on NM_018014.4) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs1466757077, COSV59625455; called by muse, mutect2, varscan2
- BCL11A | c.1415C>T p.T472M (on ENST00000335712 / NM_001365609.1; = p.T506M on NM_018014.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.482); catalogued as rs919252266, COSV59633959; called by muse, mutect2, varscan2
- BCOR | c.2986C>T p.R996W | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100653974; called by muse, mutect2, varscan2
- BMP1 | c.1839dup p.N614Qfs*21 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | catalogued as rs758822270; called by mutect2, varscan2
- BMP5 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 102/273 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369737308; called by muse, mutect2, varscan2
- BNC1 | c.1511C>T p.T504M | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs189311441, COSV61758122; called by muse, mutect2, varscan2
- BNIP3L | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV101020112; called by muse, mutect2, varscan2
- BPI | c.106G>A p.V36I (on ENST00000262865; = p.V32I on NM_001725.3) | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs145265915; called by muse, mutect2, varscan2
- BRD4 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768982122, COSV54583565; called by muse, mutect2, varscan2
- BRF2 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751368381, COSV55105035; called by muse, mutect2, varscan2
- BRPF3 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV60209438; called by muse, mutect2, varscan2
- BRS3 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.639); catalogued as rs1407696662, COSV101036646; called by muse, mutect2, varscan2
- BSND | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs74315288, CM013301; called by muse, mutect2, varscan2
- BTAF1 | c.4416T>A p.S1472R | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99795725; called by muse, mutect2, varscan2
- C15orf40 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs1002090929, COSV100417422; called by muse, mutect2, varscan2
- C1QTNF8 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs764829937, COSV100116485; called by muse, mutect2, varscan2
- C4A | c.2777C>T p.A926V | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as rs762474221, COSV71179157; called by muse, mutect2, varscan2
- C7 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.066); catalogued as rs369760989, COSV57479843; called by muse, mutect2, varscan2
- C7orf26 | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs747631940, COSV100732988; called by muse, mutect2, varscan2
- C9orf43 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as rs746600411, COSV99928555; called by muse, mutect2, varscan2
- CA7 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs371450569; called by muse, mutect2, varscan2
- CA8 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.64); catalogued as rs374430594; called by muse, mutect2, varscan2
- CABIN1 | c.4564C>T p.R1522C | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs761062938, COSV99573887; called by muse, mutect2, varscan2
- CACNA1G | c.4441G>A p.V1481I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772369809, COSV100662427; called by muse, mutect2, varscan2
- CACNA1H | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs770371468, CM032208, COSV61987315; called by muse, mutect2, varscan2
- CACNG3 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.732); catalogued as rs746004181, COSV50065372; called by muse, mutect2, varscan2
- CALN1 | c.149G>A p.R50Q (on ENST00000329008 / NM_001017440.3; = p.R92Q on NM_031468.4) | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as rs753498969, COSV61118039, COSV61119958; called by muse, mutect2, varscan2
- CAMKK1 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs750605303, COSV99340518; called by muse, mutect2, varscan2
- CAPN3 | c.1669G>A p.V557M | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs930071521, COSV58825843; called by muse, mutect2, varscan2
- CARMIL3 | c.3157C>T p.R1053W | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs748810187, COSV100549309; called by muse, mutect2, varscan2
- CASD1 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs749883611, COSV51972613; called by muse, mutect2, varscan2
- CASP2 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368449253; called by muse, mutect2, varscan2
- CCDC116 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.276); catalogued as rs200945059, COSV53041668, COSV53042643; called by muse, mutect2, varscan2
- CCDC18 | c.1501G>A p.V501I (on ENST00000343253 / NM_001306076.1; = p.V502I on NM_206886.4) | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs774643097, COSV58141081; called by muse, mutect2, varscan2
- CCDC59 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV50259297; called by muse, mutect2, varscan2
- CCKBR | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.023); catalogued as rs1161275603, COSV100583080; called by muse, mutect2, varscan2
- CCL26 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 51/233 reads (22%) | catalogued as rs200686147, COSV50013634; called by muse, mutect2, varscan2
- CCN4 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as rs1261414685, COSV51532771; called by muse, mutect2, varscan2
- CCT8L2 | c.548T>G p.L183R | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100743053, COSV63462385; called by muse, mutect2, varscan2
- CD14 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs571768081, COSV100117641; called by muse, mutect2, varscan2
- CD276 | c.1120C>T p.R374W (on ENST00000318443 / NM_001024736.2; = p.R156W on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754785892, COSV100573437; called by muse, mutect2, varscan2
- CD9 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs370435329; called by muse, mutect2, varscan2
- CDAN1 | c.572C>T p.T191M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs759985728, COSV99142181; called by muse, mutect2
- CDC34 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 194/560 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1568330110, COSV53118423; called by muse, mutect2, varscan2
- CDC37 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 85/257 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs1302729807, COSV55769832, COSV55770154; called by muse, mutect2, varscan2
- CDC42EP3 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs1206032439, COSV54874653; called by muse, mutect2, varscan2
- CDC42SE2 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 25/90 reads (28%) | catalogued as COSV64760054; called by muse, mutect2, varscan2
- CDH20 | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.627); catalogued as rs143169143; called by muse, mutect2, varscan2
- CDH20 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.053); catalogued as rs542150773, COSV99406409; called by muse, mutect2, varscan2
- CDH4 | c.815A>G p.D272G | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV100849476; called by muse, mutect2, varscan2
- CECR2 | c.2585C>T p.P862L (on ENST00000342247 / NM_001290047.2; = p.P679L on NM_001290046.1) | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.829); catalogued as rs762336876, COSV99378953; called by muse, mutect2, varscan2
- CELF2 | c.1127C>T p.T376M (on ENST00000416382 / NM_001025077.3; = p.T389M on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV100258199; called by muse, mutect2, varscan2
- CELF6 | c.1417C>T p.R473W | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760379153, COSV54718562; called by muse, mutect2, varscan2
- CELSR1 | c.6638C>T p.T2213M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs745599523, COSV53093415; called by muse, mutect2, varscan2
- CELSR1 | c.3367G>A p.V1123M | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as rs1461873935, COSV99419776; called by muse, mutect2, varscan2
- CELSR3 | c.7816G>A p.A2606T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50939862; called by muse, mutect2, varscan2
- CEP72 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.236); catalogued as rs199576925; called by muse, mutect2, varscan2
- CEP95 | c.2170C>T p.R724C | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs374766116; called by muse, mutect2, varscan2
- CFAP44 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs754584003, COSV99870249; called by muse, mutect2, varscan2
- CFAP46 | c.7645C>T p.R2549* | Nonsense Mutation (SNP) | VAF 47/123 reads (38%) | catalogued as rs973200087, COSV99584215; called by muse, mutect2, varscan2
- CFAP58 | c.2348C>T p.T783M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs140537135; called by muse, mutect2, varscan2
- CFTR | c.2279C>T p.T760M | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs397508359, CM993863, COSV99133601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD3 | c.515T>C p.L172P | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100391601; called by muse, mutect2, varscan2
- CHD5 | c.3398G>A p.R1133H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs1390212280, COSV52420644; called by muse, mutect2, varscan2
- CHIA | c.1271C>T p.S424L (on ENST00000343320; = p.S316L on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as rs754393219, COSV58475780; called by muse, mutect2, varscan2
- CHRNA3 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199887463; called by muse, mutect2, varscan2
- CHTF18 | c.2875G>A p.E959K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs958577613, COSV50210161; called by muse, mutect2, varscan2
- CKAP4 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs749256244, COSV100952516; called by muse, mutect2, varscan2
- CLCN4 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 197/484 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs758243017, COSV66467985; called by muse, mutect2, varscan2
- CLDN25 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs918393061, COSV71620433, COSV71620507; called by muse, mutect2, varscan2
- CLK3 | c.634C>T p.R212C (on ENST00000395066 / NM_001130028.1; = p.R64C on NM_003992.4) | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs371659907; called by muse, mutect2, varscan2
- CNR1 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 102/260 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.707); catalogued as rs142010122; called by muse, mutect2, varscan2
- CNTNAP2 | c.2200C>T p.R734C | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as rs775506190, COSV62271851; called by muse, mutect2, varscan2
- COL1A2 | c.3367C>T p.R1123C | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs765271962, COSV51958062, COSV51959307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL22A1 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs200816628, COSV100280467, COSV57327951; called by muse, mutect2, varscan2
- COL2A1 | c.4117G>A p.V1373I | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778382364, COSV61534119; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A1 | c.2275G>A p.V759M | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as rs373383488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL9A3 | c.900G>A p.P300= | Splice Region (SNP) | VAF 22/82 reads (27%) | catalogued as rs754133383, COSV100673562; called by muse, mutect2, varscan2
- CPSF1 | c.4186C>T p.R1396C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1554862106, COSV100450677; called by muse, mutect2, varscan2
- CPSF1 | c.2365C>T p.R789W | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201892110; called by muse, mutect2, varscan2
- CPSF1 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as rs782714249, COSV100574745; called by muse, mutect2, varscan2
- CPZ | c.1510C>T p.R504W (on ENST00000360986 / NM_001014447.3; = p.R493W on NM_003652.3) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs777229492, CM124432, COSV59922994, COSV59925029; called by muse, mutect2, varscan2
- CRACDL | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as rs775019973, COSV67407590, COSV67409395, COSV67410310; called by muse, mutect2, varscan2
- CRTAC1 | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 26/84 reads (31%) | catalogued as rs776273208, COSV54002538; called by muse, mutect2, varscan2
- CRYGB | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1364244339, COSV53680915; called by muse, mutect2, varscan2
- CSMD1 | c.2122C>T p.R708* (on ENST00000520002; = p.R707* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV59352312; called by muse, mutect2
- CSMD1 | c.1919C>T p.A640V (on ENST00000520002; = p.A639V on NM_033225.6) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); catalogued as rs183309351, COSV59314590; called by muse, mutect2, varscan2
- CSNK1G1 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777544, CM145529, COSV57311625; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTRL | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs144794688; called by muse, mutect2, varscan2
- CTSF | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 87/201 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100074474; called by muse, mutect2, varscan2
- CUL1 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 58/267 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs868836509, COSV100296894; called by muse, mutect2, varscan2
- CUL2 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV66079515; called by muse, mutect2, varscan2
- CUX2 | c.3202C>T p.R1068W | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55647487; called by mutect2, varscan2
- CYP11B2 | c.449C>A p.S150* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as rs768685630, COSV100011321, COSV100011338; called by muse, mutect2, varscan2
- CYP27C1 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745713688, COSV58866704; called by muse, mutect2, varscan2
- CYP2A13 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs753627766, COSV100386989; called by muse, mutect2, varscan2
- CYP3A7 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146249663, COSV60483285; called by muse, mutect2, varscan2
- DAGLB | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.565); catalogued as rs769792440, COSV99766120; called by muse, mutect2, varscan2
- DCTN5 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs756086132, COSV100266057; called by muse, mutect2, varscan2
- DDX19B | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 86/206 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as rs1047256162, COSV99850166; called by muse, mutect2, varscan2
- DDX47 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as rs923616212, COSV61912261; called by muse, mutect2, varscan2
- DELE1 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1488432158, COSV99519994; called by muse, mutect2, varscan2
- DGKK | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as rs372440338, COSV101053181; called by muse, mutect2, varscan2
- DHX37 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); catalogued as rs761194412, COSV100439422; called by muse, mutect2, varscan2
- DHX38 | c.2992C>T p.R998W | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51698151; called by muse, mutect2, varscan2
- DIABLO | c.328G>A p.A110T (on ENST00000443649 / NM_001278303.1; = p.A183T on NM_019887.6) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); catalogued as rs781358968, COSV99928046; called by muse, mutect2, varscan2
- DIP2A | c.3826C>T p.R1276C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs760071686, COSV59477212; called by muse, mutect2
- DIP2C | c.1766C>T p.A589V | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV99793480; called by muse, mutect2, varscan2
- DIP2C | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs536406182, COSV55176164; called by muse, mutect2, varscan2
- DLGAP1 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV59800338; called by muse, mutect2, varscan2
- DLGAP2 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs765129726, COSV101422602; called by muse, mutect2
- DMXL2 | c.3424G>A p.D1142N | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs761879645, COSV51857083; called by muse, mutect2, varscan2
- DNAAF5 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 61/339 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs749838774, COSV99860241; called by muse, mutect2, varscan2
- DNAAF5 | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779271163, COSV99860244; called by muse, mutect2, varscan2
- DNAH10 | c.5092G>A p.V1698M (on ENST00000409039; = p.V1637M on NM_207437.3) | Missense Mutation (SNP) | VAF 87/173 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs369082437; called by muse, mutect2, varscan2
- DNAH10 | c.9320G>A p.R3107H (on ENST00000409039; = p.R3046H on NM_207437.3) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs1276943171, COSV101292571; called by muse, mutect2, varscan2
- DNAH11 | c.6326A>G p.D2109G | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100180540; called by muse, mutect2, varscan2
- DNAH2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs760100076, COSV50013789; called by muse, mutect2
- DNAH2 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 23/40 reads (58%) | catalogued as rs1247906703, COSV99318503; called by muse, mutect2, varscan2
- DNAH5 | c.12380G>A p.R4127H | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs762555871, COSV54221607; called by muse, mutect2
- DNAJB9 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 69/319 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs755504350, COSV50812011; called by muse, mutect2, varscan2
- DNM2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 129/385 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568283768, COSV100117874; called by muse, mutect2, varscan2
- DNMT3A | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1277241617, COSV99264163; called by muse, mutect2
- DNMT3A | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs758881009, COSV53044554, COSV53064654, COSV53087534; called by muse, mutect2, varscan2
- DNTTIP1 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768988044, COSV101010002; called by muse, mutect2, varscan2
- DOCK1 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771775279, COSV54755411; called by muse, mutect2, varscan2
- DOCK1 | c.1318G>T p.G440* | Nonsense Mutation (SNP) | VAF 92/242 reads (38%) | catalogued as COSV99732212; called by muse, mutect2, varscan2
- DOCK1 | c.2138C>T p.T713M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1249062472, COSV99732215; called by muse, mutect2, varscan2
- DOCK8 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs771753565, COSV66635615; ClinVar: uncertain significance; called by muse, mutect2
- DRP2 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758782031, COSV65809493; called by muse, mutect2, varscan2
- DSC2 | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs777004957, COSV99199841; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYSF | c.3277C>T p.R1093C | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs372817333; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYSF | c.3751C>T p.R1251W | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs753817458, COSV99250066; called by muse, mutect2, varscan2
- E2F2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62276426; called by muse, mutect2, varscan2
- ECPAS | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs770702141, COSV99399125; called by muse, mutect2, varscan2
- EEF1A2 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV99419807; called by muse, mutect2, varscan2
- EHBP1L1 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs565396684, COSV100499986; called by muse, mutect2, varscan2
- EIF2AK1 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99552248; called by muse, mutect2, varscan2
- EIF2D | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs147679184; called by muse, mutect2, varscan2
- ELOB | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs776112584, COSV51942106; called by muse, mutect2, varscan2
- ELOVL4 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs764637851, COSV63953899; called by muse, mutect2, varscan2
- EMILIN2 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772348013, COSV54420928; called by muse, mutect2, varscan2
- ENPP6 | c.1059G>A p.W353* | Nonsense Mutation (SNP) | VAF 7/111 reads (6%) | catalogued as COSV99699106; called by muse, mutect2
- EP400 | c.4841C>T p.P1614L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs755355979, COSV100202076; called by muse, varscan2
- EP400 | c.9230C>T p.A3077V | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as rs1157861706, COSV100202083, COSV57780990; called by muse, mutect2, varscan2
- EPB42 | c.1919G>A p.R640H (on ENST00000441366 / NM_001114134.2; = p.R670H on NM_000119.3) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1287191197, COSV100281666; ClinVar: uncertain significance; called by muse, mutect2
- EPC1 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 43/80 reads (54%) | catalogued as COSV53925685; called by muse, mutect2, varscan2
- EPG5 | c.4501C>T p.R1501W | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs370776793; called by muse, mutect2, varscan2
- EPHB2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1175066410, COSV101007359; called by muse, mutect2, varscan2
- ERN2 | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs374022289, COSV56834316; called by muse, mutect2, varscan2
- ESX1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs782410327, COSV65424665, COSV65425372; called by muse, mutect2, varscan2
- EVC2 | c.2152G>A p.G718S | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762306367, COSV60393805; called by muse, mutect2, varscan2
- EXD3 | c.2575G>A p.A859T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as rs898058049, COSV59809715; called by muse, mutect2
- EXOC3 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.39); catalogued as rs199822297; called by muse, varscan2
- EXOC3 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs755899854, COSV100155528; called by muse, mutect2, varscan2
- EXOC8 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs777719915, COSV50479156; called by muse, mutect2, varscan2
- FAF1 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 129/318 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs147358189, COSV65637384; called by muse, mutect2, varscan2
- FAF2 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 70/181 reads (39%) | catalogued as rs1216935239, COSV56129951; called by muse, mutect2, varscan2
- FAM193A | c.1540A>T p.S514C | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100219541; called by muse, mutect2, varscan2
- FAM221A | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as rs751870008, COSV100794379; called by muse, mutect2, varscan2
- FAM237A | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200894319, COSV101405585; called by muse, mutect2, varscan2
- FAM78A | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV100953455; called by muse, mutect2, varscan2
- FAM83A | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1483078150, COSV52684675; called by muse, mutect2, varscan2
- FBF1 | c.2645G>A p.R882H (on ENST00000586717; = p.R896H on NM_001319193.1) | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1479510565, COSV59865734; called by muse, mutect2, varscan2
- FBLN5 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs776279224, COSV50908787; called by muse, mutect2, varscan2
- FBN2 | c.3202C>T p.R1068W | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761958762, COSV52494404; called by muse, mutect2, varscan2
- FBXO40 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as rs756122429, COSV57523615; called by muse, mutect2, varscan2
- FBXW10 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as rs759696705, COSV100111710; called by muse, mutect2, varscan2
- FBXW11 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV99441334, COSV99441425; called by muse, mutect2, varscan2
- FGD5 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs749435304, COSV53247320; called by muse, mutect2, varscan2
- FGD5 | c.4115G>A p.R1372Q | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751172332, COSV99548864; called by muse, mutect2, varscan2
- FGF23 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs780315628, COSV99426493; called by muse, mutect2, varscan2
- FGF8 | c.303C>T p.F101= (on ENST00000344255 / NM_033164.4; = p.F83= on NM_006119.6) | Splice Region (SNP) | VAF 12/40 reads (30%) | catalogued as rs369110952, COSV100199426; called by muse, mutect2, varscan2
- FHOD1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as rs774140986, COSV99264462; called by muse, mutect2, varscan2
- FHOD3 | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758818742, COSV99940480; called by muse, mutect2, varscan2
- FLNB | c.2173G>A p.V725M | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs201814013, COSV55898251; called by muse, mutect2, varscan2
- FLNC | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776362922, COSV57965274; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLRT1 | c.1340C>T p.T447M | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs779400742, COSV55358859; called by muse, mutect2, varscan2
- FLT4 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.738); catalogued as COSV99988688; called by muse, mutect2, varscan2
- FLT4 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); catalogued as rs751948166, COSV99987793; called by muse, mutect2, varscan2
- FNIP1 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as COSV100330576; called by muse, mutect2, varscan2
- FOLR3 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as rs554883482, COSV61530129; called by muse, mutect2, varscan2
- FOXK2 | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs902836810, COSV58877757; called by muse, mutect2, varscan2
- FOXM1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 93/286 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs137928577, COSV61206733; called by muse, mutect2, varscan2
- FOXP1 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1240117000, COSV100562278, COSV59536958, COSV59555654; called by muse, mutect2, varscan2
- FREM1 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs763640629, COSV101085289; called by muse, mutect2, varscan2
- FRMD4B | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs538012715, COSV101273655; called by muse, mutect2, varscan2
- FRMD8 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1384045229, COSV100454830; called by muse, mutect2, varscan2
- FRMPD3 | c.4549G>A p.E1517K | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as rs775247008, COSV99345918; called by muse, mutect2, varscan2
- FSCN1 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as rs1410800643, COSV100435271; called by muse, mutect2, varscan2
- FSTL4 | c.2222G>A p.R741H | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs758660966, COSV54790430; called by muse, mutect2, varscan2
- FXR2 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.18); catalogued as rs778721641, COSV51468462; called by muse, mutect2, varscan2
- GAB2 | c.602G>A p.R201Q (on ENST00000361507 / NM_080491.3; = p.R163Q on NM_012296.3) | Missense Mutation (SNP) | VAF 157/394 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs539815954, COSV100416789; called by muse, mutect2, varscan2
- GABRB1 | c.139G>T p.G47* | Nonsense Mutation (SNP) | VAF 118/314 reads (38%) | catalogued as COSV99783190; called by muse, mutect2, varscan2
- GABRE | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs753240533, COSV100944359; called by muse, mutect2, varscan2
- GAL3ST2 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs202108971, COSV51950164; called by muse, mutect2, varscan2
- GALNT17 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 72/344 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs1328660099, COSV100355100, COSV61157811; called by muse, mutect2, varscan2
- GALNT2 | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100795874, COSV64196252; called by muse, mutect2, varscan2
- GALNT6 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 41/108 reads (38%) | catalogued as rs760495034, COSV62542743; called by muse, mutect2, varscan2
- GBGT1 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs1335402262, COSV100923785; called by muse, varscan2
- GCM1 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs747467471, COSV52521619; called by muse, mutect2, varscan2
- GFRA1 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as rs752981166, COSV62611549; called by muse, mutect2
- GFRAL | c.499T>A p.C167S | Missense Mutation (SNP) | VAF 140/364 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100475788; called by muse, mutect2, varscan2
- GGN | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.072); catalogued as COSV99287656; called by muse, mutect2, varscan2
- GIMAP4 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV55431237, COSV99751080; called by muse, mutect2
- GIPC3 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.983); catalogued as rs201268436; ClinVar: uncertain significance; called by muse, mutect2
- GJB1 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs749796053, COSV62139879; called by muse, mutect2, varscan2
- GLDC | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs148775220, COSV100394611; called by muse, mutect2, varscan2
- GLG1 | c.2353C>T p.R785C | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1567462208, COSV52671003; called by muse, mutect2, varscan2
- GLI3 | c.681G>A p.A227= | Splice Region (SNP) | VAF 22/119 reads (18%) | catalogued as rs752998397, COSV67894163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLT6D1 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.403); catalogued as rs370842340, COSV65628678; called by muse, mutect2
- GLT8D2 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.873); catalogued as rs150432657, COSV62563529; called by muse, mutect2, varscan2
- GLYR1 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 70/197 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58927130, COSV58928003; called by muse, mutect2, varscan2
- GNL2 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs748817671, COSV100895038; called by muse, mutect2, varscan2
- GNPTAB | c.2614G>A p.V872I | Missense Mutation (SNP) | VAF 136/498 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs775948211, COSV54777029; called by muse, mutect2, varscan2
- GPAA1 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1278283377, COSV100284187; called by muse, mutect2, varscan2
- GPATCH1 | c.2740G>A p.V914M | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs199830028; called by muse, mutect2, varscan2
- GPATCH8 | c.2719C>T p.R907C | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs139161658; called by muse, mutect2, varscan2
- GPR26 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.506); catalogued as rs372084986; called by muse, mutect2, varscan2
- GRAMD1B | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.808); catalogued as rs921395364, COSV59207468, COSV59210404; called by muse, mutect2, varscan2
- GRAMD2B | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); catalogued as rs202196656; called by muse, mutect2, varscan2
- GRB7 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 109/293 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as rs779232294, COSV58446552; called by muse, mutect2, varscan2
- GRIK3 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as rs758626562, COSV100902263, COSV99057960; called by muse, mutect2, varscan2
- GRIK5 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765252385, COSV53479273; called by muse, mutect2, varscan2
- GRIPAP1 | c.2326G>A p.V776I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.747); catalogued as COSV54415076; called by muse, mutect2, varscan2
- GRK2 | c.1230C>T p.A410= | Splice Region (SNP) | VAF 74/220 reads (34%) | catalogued as rs1381279717, COSV57952526; called by muse, mutect2, varscan2
- GRM3 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 61/365 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64472529; called by muse, mutect2, varscan2
- GTF2H4 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as COSV99462167; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1554532942, COSV57032460; called by mutect2, varscan2
- GTF3C1 | c.2017C>T p.R673* | Nonsense Mutation (SNP) | VAF 58/154 reads (38%) | catalogued as COSV62243100; called by muse, mutect2, varscan2
- GTPBP3 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.373); catalogued as COSV99344873; called by muse, mutect2, varscan2
- GUSB | c.763C>A p.L255M | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.443); catalogued as COSV100512749; called by muse, mutect2, varscan2
- HCRTR1 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs144638017; called by muse, mutect2, varscan2
- HDAC4 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs748395305, COSV100614137; called by muse, mutect2
- HDAC5 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs376431873, COSV99870993; called by muse, mutect2, varscan2
- HDGFL2 | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs199605023, COSV56683730; called by muse, mutect2, varscan2
- HDHD5 | c.481C>T p.R161W (on ENST00000336737 / NM_033070.3; = p.R131W on NM_017829.5) | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs181942834, COSV99325003; called by muse, mutect2, varscan2
- HECW1 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.038); catalogued as COSV67838374; called by muse, mutect2, varscan2
- HERC2 | c.14437G>A p.D4813N | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.99); catalogued as rs763338420, COSV99876390; called by muse, mutect2, varscan2
- HGH1 | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1050991819; called by muse, mutect2, varscan2
- HGSNAT | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs371869844; called by muse, mutect2, varscan2
- HIC2 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV101335625; called by muse, mutect2, varscan2
- HIP1R | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 97/241 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as rs376195793; called by muse, mutect2, varscan2
- HIPK1 | c.2402A>G p.N801S | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1287324280, COSV100479589; called by muse, mutect2, varscan2
- HIRA | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs782037801, COSV54272101; called by muse, varscan2
- HMGCS2 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs373202578; called by muse, mutect2, varscan2
- HMGN4 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs748353798, COSV101110249; called by muse, mutect2, varscan2
- HOOK2 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1467703698, COSV99317814; called by muse, mutect2, varscan2
- HS6ST1 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs370556993; called by muse, mutect2, varscan2
- HYOU1 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as rs781897557, COSV101345663; called by muse, mutect2, varscan2
- IAH1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.345); catalogued as rs778654141, COSV61070774; called by muse, mutect2, varscan2
- IFT140 | c.2612G>A p.R871H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs905240853, COSV99560151; called by muse, mutect2, varscan2
- IGFBP3 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs765418581, COSV99298492; called by muse, mutect2, varscan2
- IGFBP7 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs146423345, COSV55271788; called by muse, mutect2, varscan2
- IGHA2 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs781940822; called by muse, varscan2
- IGHMBP2 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 144/364 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1384314579, COSV99662497; called by muse, mutect2, varscan2
- IGHV1-58 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.177); catalogued as rs369851071; called by muse, mutect2
- IGLV3-1 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as rs773986506; called by muse, mutect2, varscan2
- IGSF11 | c.259C>T p.R87W (on ENST00000393775 / NM_001015887.3; = p.R86W on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs764460197, COSV100677804; called by muse, mutect2, varscan2
- IGSF9B | c.2648C>T p.T883M | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs936090495, COSV58068794; called by muse, mutect2, varscan2
- IGSF9B | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs776113610, COSV100318302; called by muse, mutect2, varscan2
- IL17RE | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs200160526; called by muse, mutect2, varscan2
- IL2RA | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 95/261 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs147791171; called by muse, mutect2
- ILKAP | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.175); catalogued as rs747013380, COSV99611148; called by muse, mutect2, varscan2
- IMPG2 | c.3568G>A p.V1190M | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs762391776, COSV51978313, COSV99516161; called by muse, mutect2, varscan2
- INF2 | c.2310C>T p.Y770= | Splice Region (SNP) | VAF 8/12 reads (67%) | catalogued as rs758454108, COSV99384265; ClinVar: likely benign; called by muse, mutect2, varscan2
- INKA1 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs942371771, COSV60967070; called by muse, mutect2, varscan2
- INSC | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as rs780043285, COSV65411842; called by muse, mutect2, varscan2
- INTS10 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); catalogued as rs369555554; called by muse, mutect2, varscan2
- IPO9 | c.2719C>T p.R907C | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs780621165, COSV100843544; called by muse, mutect2, varscan2
- IQCE | c.671A>T p.Q224L | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100383674; called by muse, mutect2
- IQSEC3 | c.1544C>T p.T515M (on ENST00000538872 / NM_001170738.2; = p.T212M on NM_015232.1) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.132); catalogued as rs782088139, COSV100407552; called by muse, mutect2, varscan2
- IQSEC3 | c.2258G>A p.R753Q (on ENST00000538872 / NM_001170738.2; = p.R450Q on NM_015232.1) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs527558225, COSV58285414; called by muse, mutect2
- IRAG1 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370614126; called by muse, mutect2, varscan2
- ISLR2 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs1358213899, COSV62302436; called by muse, mutect2, varscan2
- ITGA6 | c.2960C>T p.A987V (on ENST00000442250; = p.A948V on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/333 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs1331464932, COSV99905984; called by muse, mutect2, varscan2
- ITIH3 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.432); catalogued as rs200095865; called by muse, mutect2, varscan2
- ITIH5 | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); catalogued as rs768283912, COSV53660329; called by muse, mutect2, varscan2
- ITPR3 | c.2468G>A p.R823Q | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as rs760394466, COSV65415748; called by muse, varscan2
- ITPR3 | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 72/166 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100968025; called by muse, varscan2
- ITPRIPL1 | c.1417C>T p.R473W (on ENST00000439118 / NM_001008949.3; = p.R481W on NM_178495.6) | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755732616, COSV100742237; called by muse, mutect2, varscan2
- JAK2 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs368927897, CM1111733, COSV67590089, COSV67606947; called by muse, mutect2, varscan2
- KAT8 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as rs963784714, COSV54898951; called by muse, mutect2, varscan2
- KCND1 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs781928708, COSV99502118; called by muse, mutect2
- KCTD10 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV99949401; called by muse, mutect2, varscan2
- KDM3B | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 14/250 reads (6%) | catalogued as COSV58687357; called by muse, mutect2
- KDM6A | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100938533; called by muse, mutect2, varscan2
- KDM6B | c.2014G>C p.D672H | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as COSV54685792; called by muse, mutect2, varscan2
- KIAA0232 | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 91/221 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); catalogued as rs370637729; called by muse, mutect2, varscan2
- KIAA1522 | c.1351C>T p.R451W (on ENST00000373480 / NM_001198972.2; = p.R510W on NM_020888.3) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs200772688; called by muse, mutect2, varscan2
- KIAA2026 | c.3128C>T p.P1043L | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs375654717; called by muse, mutect2, varscan2
- KIF1C | c.2776C>T p.R926W | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.265); catalogued as rs765376957, COSV100297287; called by mutect2, varscan2
- KIF20B | c.5438G>A p.R1813Q (on ENST00000371728 / NM_001284259.2; = p.R1773Q on NM_016195.4) | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs757350037, COSV53317286; called by muse, mutect2, varscan2
- KIRREL3 | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs367963236; called by muse, mutect2, varscan2
- KIZ | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs1165353786, COSV99852353; called by muse, mutect2, varscan2
- KLF9 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772506798, COSV101009616; called by muse, mutect2, varscan2
- KLHDC7A | c.2158G>A p.V720M | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs774526487, COSV68769965; called by muse, mutect2, varscan2
- KLHL10 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99509426; called by muse, mutect2, varscan2
- KLHL15 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.255); catalogued as COSV100044406; called by muse, mutect2, varscan2
- KLHL25 | c.131T>C p.M44T | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs909148165, COSV100563706; called by muse, mutect2, varscan2
- KLK7 | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as rs200158151, COSV58344931; called by muse, mutect2, varscan2
- KLRK1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as rs774643686, COSV99555235; called by muse, mutect2, varscan2
- KRT14 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 96/281 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs778867001, COSV51420356, COSV99391037; called by muse, mutect2, varscan2
- KRT16 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as rs1405646148, COSV56967380; called by muse, mutect2, varscan2
- KRT19 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs758074102, COSV99563255; called by muse, mutect2, varscan2
- KRT26 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 77/218 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs185320223, COSV56971709; called by muse, mutect2, varscan2
- KRT7 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs376567055; called by muse, mutect2, varscan2
- KRT83 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 91/279 reads (33%) | catalogued as rs755397937, COSV99531866, COSV99531922; called by muse, mutect2, varscan2
- KRT85 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs201639644, COSV99225670; called by muse, mutect2, varscan2
- KRTAP27-1 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101239767; called by muse, mutect2, varscan2
- KSR1 | c.2227C>T p.R743C (on ENST00000644974 / NM_001367810.1; = p.R628C on NM_014238.2) | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs750142365, COSV99260599; called by muse, mutect2, varscan2
- L3MBTL4 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 162/474 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs777141155, COSV99530801; called by muse, mutect2, varscan2
- LANCL2 | c.1151C>T p.T384M | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372080148; called by muse, mutect2, varscan2
- LARP1 | c.2333G>A p.R778H (on ENST00000518297 / NM_033551.3; = p.R701H on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.014); catalogued as rs926314441, COSV60429510; called by muse, mutect2
- LGALS9 | c.547G>A p.G183S (on ENST00000395473 / NM_009587.3; = p.G151S on NM_002308.4) | Missense Mutation (SNP) | VAF 154/660 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs746362908, COSV56348030; called by muse, mutect2, varscan2
- LIG1 | c.2518G>A p.A840T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs780457620, COSV54390019, COSV99619310; called by muse, mutect2, varscan2
- LILRB4 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs146946125, COSV99553745; called by muse, mutect2, varscan2
- LLGL2 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778701779, COSV99390412; called by muse, mutect2, varscan2
- LPCAT1 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs746382072, COSV52036526; called by muse, mutect2, varscan2
- LRP5 | c.4268C>T p.P1423L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.296); catalogued as rs748143518, COSV99592557; called by muse, mutect2, varscan2
- LRRC32 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs200593139, COSV99477248; called by muse, mutect2, varscan2
- LRSAM1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs754527468, COSV100031841; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRWD1 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs376560819; called by muse, mutect2, varscan2
- LSM11 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs763310569, COSV53847875; called by muse, mutect2, varscan2
- LTBP2 | c.3890C>T p.P1297L | Missense Mutation (SNP) | VAF 79/105 reads (75%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.749); catalogued as rs771009684, COSV56212214; called by muse, mutect2, varscan2
- LTBP4 | c.2153C>T p.P718L (on ENST00000308370 / NM_001042544.1; = p.P681L on NM_003573.2) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs553642363, COSV99199314; called by muse, mutect2, varscan2
- LTBP4 | c.3012C>T p.D1004= (on ENST00000308370 / NM_001042544.1; = p.D967= on NM_003573.2) | Splice Region (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99198714; called by muse, mutect2
- LTBP4 | c.3190G>A p.V1064M (on ENST00000308370 / NM_001042544.1; = p.V1027M on NM_003573.2) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs748078658, COSV99180351; ClinVar: likely benign; called by muse, mutect2, varscan2
- LY75 | c.3043C>T p.R1015C | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs780326292, COSV99716573; called by muse, mutect2, varscan2
- LZTR1 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs762005490, COSV53149571; called by muse, mutect2
- MAFG | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV100155707; called by muse, mutect2, varscan2
- MAGEB6 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as rs750281330, COSV66872058; called by muse, mutect2, varscan2
- MAMDC4 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.58); catalogued as rs371823485; called by muse, mutect2, varscan2
- MAN2B1 | c.1517C>T p.T506M | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as rs139255957, COSV99667268; called by muse, mutect2, varscan2
- MANEA | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs776851480, COSV100721674, COSV62589766; called by muse, mutect2, varscan2
- MAP1B | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs200451397, COSV57094114; called by muse, mutect2, varscan2
- MAP3K12 | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.211); catalogued as rs149876591; called by muse, mutect2, varscan2
- MAP4K2 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.305); catalogued as rs202006912, COSV53640439, COSV53644713; called by muse, mutect2
- MAP7 | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs34607647, COSV100644007; called by muse, varscan2
- MAP7D2 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 139/314 reads (44%) | catalogued as rs1242055641, COSV65525701; called by muse, mutect2, varscan2
- MAPK15 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.398); catalogued as rs782627573, COSV100568063; called by muse, mutect2, varscan2
- MARCHF6 | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 93/492 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs780061610, COSV99930111; called by muse, mutect2, varscan2
- MAST2 | c.2807C>T p.A936V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs201897607; called by muse, mutect2, varscan2
- MAT2A | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.807); catalogued as rs1558798457, COSV52090196; called by muse, mutect2, varscan2
- MCF2L | c.445G>A p.V149I (on ENST00000375608; = p.V117I on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs751605602, COSV100982876; called by muse, mutect2, varscan2
- MCM3 | c.1817G>A p.R606H (on ENST00000229854 / NM_001366374.2; = p.R596H on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs928034762, COSV100009023; called by muse, mutect2
- MCOLN1 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs200297215, COSV51178899; called by muse, mutect2, varscan2
- MCRS1 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs756538123, COSV100657417; called by muse, mutect2, varscan2
- MDN1 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs780595213, COSV101021764; called by muse, mutect2, varscan2
- MECP2 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 116/325 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57652274; called by muse, mutect2, varscan2
- MEGF8 | c.6739C>T p.R2247C (on ENST00000251268 / NM_001271938.2; = p.R2180C on NM_001410.3) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs1438199181, COSV99238678; called by muse, varscan2
- MERTK | c.2590G>A p.V864I | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs557004700, COSV54923921; called by muse, mutect2, varscan2
- MIS12 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 46/70 reads (66%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs370045855; called by muse, mutect2, varscan2
- MKNK1 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs200209678; called by muse, mutect2, varscan2
- MMP14 | c.976G>A p.V326M | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs747054970, COSV100314296; called by muse, mutect2, varscan2
- MMRN1 | c.3146C>T p.P1049L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1236756752, COSV53334893; called by muse, mutect2, varscan2
- MOB3A | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs998560047, COSV63866470; called by muse, mutect2, varscan2
- MOCS1 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs142478972; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MORF4L2 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 118/329 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as rs1192153079, COSV100846395; called by muse, mutect2, varscan2
- MPP5 | c.1939G>A p.D647N | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs776887584, COSV99907360; called by muse, mutect2, varscan2
- MRGPRX3 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs373134264; called by muse, mutect2, varscan2
- MROH7 | c.3214C>T p.R1072W | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs754506772, COSV100273961; called by muse, mutect2, varscan2
- MRPL2 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as rs899746782, COSV99432525; called by muse, varscan2
- MRPL28 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776436317, COSV99170790; called by muse, mutect2, varscan2
- MRPL49 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs368037720; called by muse, mutect2, varscan2
- MRTFB | c.2864G>A p.R955Q (on ENST00000571589 / NM_001365412.2; = p.R905Q on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs752930290, COSV100371746; called by muse, mutect2, varscan2
- MSLNL | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as rs542551840, COSV53499256; called by muse, mutect2, varscan2
- MTA1 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs1446848077, COSV100495447; called by mutect2, varscan2
- MTREX | c.2305C>T p.R769C | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57925952; called by muse, mutect2
- MUC17 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as rs765830366, COSV59331794, COSV59332615; called by muse, mutect2, varscan2
- MUC4 | c.15463C>T p.R5155C (on ENST00000463781 / NM_018406.7; = p.R919C on NM_004532.6) | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as rs751791718, COSV100206269; called by muse, mutect2, varscan2
- MYH4 | c.3575C>T p.T1192M | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as rs202092228, COSV55124413, COSV99702078; called by muse, mutect2, varscan2
- MYO1C | c.2005G>A p.E669K (on ENST00000648651 / NM_001080779.2; = p.E634K on NM_033375.5) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs926209230, COSV100704533; called by muse, mutect2
- MYO1C | c.1358C>T p.T453M (on ENST00000648651 / NM_001080779.2; = p.T418M on NM_033375.5) | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs901689744, COSV100704534; called by muse, mutect2, varscan2
- MYO1D | c.298A>C p.I100L | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100554864; called by muse, mutect2, varscan2
- MYO1G | c.1867G>A p.A623T | Missense Mutation (SNP) | VAF 93/422 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.212); catalogued as rs374130084, COSV51853493; called by muse, mutect2, varscan2
- MYO3B | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs200712982; called by muse, mutect2, varscan2
- NAGK | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 132/379 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs754915910, COSV54903272; called by muse, mutect2, varscan2
- NAP1L5 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV52018801, COSV99985929; called by muse, mutect2, varscan2
- NAV1 | c.3251G>A p.R1084Q | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs753418926, COSV55218535, COSV55219404; called by muse, mutect2, varscan2
- NCAN | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1051841821, COSV53059062; called by muse, mutect2, varscan2
- NCKAP1L | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764942199, COSV53211843; called by muse, mutect2, varscan2
- NCKAP5L | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs770524990, COSV100259159; called by muse, varscan2
- NEB | c.2515A>G p.T839A | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779630318, COSV99427154; called by muse, mutect2, varscan2
- NEDD4L | c.1090C>T p.R364C (on ENST00000400345 / NM_001144967.3; = p.R243C on NM_001144964.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.731); catalogued as rs780617420, COSV99896354; called by muse, mutect2, varscan2
- NEFL | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.139); catalogued as rs558941336, COSV99648151; called by muse, varscan2
- NEK6 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.206); catalogued as rs148262318; called by muse, mutect2, varscan2
- NF1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as rs149003051, COSV100645996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NIPSNAP2 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 87/460 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as rs760837804, COSV100436642; called by muse, mutect2, varscan2
- NKD2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.201); catalogued as rs745548994, COSV99723680; called by muse, mutect2, varscan2
- NLRP7 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 160/441 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as rs367827849, COSV60181655; called by muse, mutect2, varscan2
- NME7 | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 36/104 reads (35%) | catalogued as rs781410209, COSV63166598; called by muse, mutect2, varscan2
- NMT2 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 103/281 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs139987933; called by muse, mutect2, varscan2
- NOBOX | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as COSV99779649; called by muse, mutect2, varscan2
- NOD1 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs375250487, COSV56112093; called by muse, mutect2, varscan2
- NOS1AP | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as rs757703119, COSV62635423; called by muse, mutect2, varscan2
- NOTCH4 | c.2041G>A p.V681M | Missense Mutation (SNP) | VAF 80/249 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs141422504; called by muse, mutect2, varscan2
- NR1D1 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs776091361, COSV52844503; called by muse, mutect2, varscan2
- NRDC | c.3115G>A p.G1039R | Missense Mutation (SNP) | VAF 79/196 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100543997; called by muse, mutect2, varscan2
- NRXN2 | c.3782C>T p.A1261V | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as rs143433650; called by muse, mutect2, varscan2
- NSD3 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as rs201510639, COSV100388894; called by muse, mutect2, varscan2
- NSMAF | c.131A>G p.K44R | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99233367; called by muse, mutect2
- NTSR1 | c.1096C>A p.L366I | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.433); catalogued as COSV100980612; called by muse, mutect2, varscan2
- NUDT19 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 98/259 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.297); catalogued as rs77865788; called by muse, mutect2, varscan2
- NUP155 | c.503C>T p.A168V (on ENST00000231498 / NM_153485.3; = p.A109V on NM_004298.4) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as rs371884662; called by muse, mutect2, varscan2
- NUP62 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs747835540, COSV61312074; called by muse, mutect2, varscan2
- NUP98 | c.4537C>T p.R1513* (on ENST00000359171 / NM_001365126.1; = p.R1496* on NM_016320.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 41/116 reads (35%) | catalogued as COSV61433047; called by muse, mutect2, varscan2
- NWD1 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs148848880; called by muse, mutect2, varscan2
- NXPH3 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs139454857; called by muse, mutect2, varscan2
- OBSCN | c.1910C>T p.T637M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs377209626, COSV99475691; called by muse, mutect2
- OBSCN | c.2408C>T p.A803V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as rs758690847, COSV52797889, COSV99483424; called by muse, mutect2, varscan2
- OBSCN | c.14788C>T p.R4930C | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs748973972, COSV99483430; called by muse, mutect2, varscan2
- OGDH | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 114/611 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs200566080, COSV99758632; called by muse, mutect2, varscan2
- OPN1MW | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.801); catalogued as rs1557159102; called by mutect2, varscan2
- OR1L3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 130/406 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs757393563, COSV100506299; called by muse, mutect2, varscan2
- OR2M7 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 14/507 reads (3%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV100522662; called by muse, mutect2
- OR2T6 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.971); catalogued as rs762508817, COSV100861612, COSV63216953; called by muse, mutect2, varscan2
- OR2Z1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV60692847; called by muse, mutect2, varscan2
- OR52N4 | c.499C>T p.L167F | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs779199912, COSV100421749; called by muse, mutect2, varscan2
- OR7G3 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs779226005, COSV100555743; called by muse, mutect2, varscan2
- OR9G4 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as rs147669235; called by muse, mutect2, varscan2
- OSBPL8 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as rs372961767; called by muse, mutect2, varscan2
- OTOL1 | c.958G>T p.G320C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100020210; called by muse, mutect2, varscan2
- PABPC1L | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs374095444; called by muse, mutect2, varscan2
- PACS1 | c.1622C>T p.T541M | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as rs745816812, COSV57700104; called by muse, mutect2, varscan2
- PAPPA | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs199822574, COSV60284182, COSV60284455; called by muse, mutect2, varscan2
- PCDH1 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54615977; called by muse, mutect2
- PCDHA12 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.877); catalogued as rs1554168680, COSV56482309; called by muse, mutect2, varscan2
- PCDHA9 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.957); catalogued as rs1554143759, COSV65324037, COSV65331516; called by muse, mutect2, varscan2
- PCDHB3 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.416); catalogued as rs1554272546, COSV99166410; called by muse, mutect2, varscan2
- PCDHB4 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 86/304 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs782115208, COSV99522465; called by muse, varscan2
- PCDHB9 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs782628377; called by muse, varscan2
- PCDHGA1 | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.502); catalogued as COSV65294825, COSV65298907; called by muse, mutect2, varscan2
- PCDHGA11 | c.2156G>A p.R719H | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); catalogued as COSV53895933; called by muse, mutect2, varscan2
- PCIF1 | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs757958805, COSV100533322; called by muse, mutect2, varscan2
- PCK2 | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757554278, COSV99394647; called by muse, mutect2, varscan2
- PCMTD2 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55063283, COSV99829572; called by muse, mutect2, varscan2
- PCNT | c.7592C>T p.T2531M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs146705703; called by muse, mutect2, varscan2
- PDE1C | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 45/307 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as rs773228744, COSV100372471, COSV58504631; called by muse, mutect2, varscan2
- PDLIM3 | c.542G>A p.R181H (on ENST00000284770 / NM_001257963.1; = p.R348H on NM_014476.6) | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs764823333, COSV52979923; called by muse, mutect2, varscan2
- PERP | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (1); PolyPhen probably damaging (0.966); catalogued as COSV101408581, COSV101408604; called by muse, mutect2, varscan2
- PEX14 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.089); catalogued as rs903736101, COSV100750273; called by muse, mutect2, varscan2
- PFKFB3 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | PolyPhen possibly damaging (0.891); catalogued as rs771681077, COSV57987476; called by muse, mutect2, varscan2
- PFKFB4 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 42/122 reads (34%) | PolyPhen probably damaging (0.999); catalogued as rs781535165, COSV99219983; called by muse, varscan2
- PGA5 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200405121, COSV56715867; called by muse, mutect2, varscan2
- PGBD4 | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as rs559941553, COSV56628947, COSV99854963; called by muse, mutect2, varscan2
- PIAS2 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 76/201 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs533422652, COSV61342735; called by muse, mutect2, varscan2
- PIK3CG | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.773); catalogued as COSV63248686; called by muse, mutect2, varscan2
- PKD1L1 | c.4738C>T p.R1580W | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs762682035, COSV56977414; called by muse, mutect2, varscan2
- PKD1L1 | c.3631G>A p.V1211I | Missense Mutation (SNP) | VAF 61/296 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs142471521; called by muse, mutect2, varscan2
- PKD1L1 | c.2968C>T p.R990W | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs147051154; called by muse, varscan2
- PKD1L2 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs202247471, COSV61416080; called by muse, mutect2, varscan2
- PKD2L1 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs2305383, COSV100559439; called by muse, mutect2, varscan2
- PKD2L2 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 60/177 reads (34%) | catalogued as rs766721598, COSV99296641; called by muse, mutect2, varscan2
- PLA2G5 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs538789160, COSV100908212; called by muse, mutect2, varscan2
- PLCB3 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 64/184 reads (35%) | catalogued as COSV99657693; called by muse, mutect2, varscan2
- PLCXD3 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1163125245, CM148214, COSV60616028; called by muse, mutect2, varscan2
- PLPBP | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.053); catalogued as rs530979693, COSV60240546; called by muse, mutect2, varscan2
- PLPP2 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as rs756459626, COSV54119655; called by muse, mutect2, varscan2
- PLPP5 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465814949, COSV100395676; called by muse, mutect2, varscan2
- PLPP7 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs778837615, COSV100952562; called by muse, mutect2, varscan2
- PLXND1 | c.1651G>A p.V551M | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs929162804, COSV60716649; called by muse, mutect2, varscan2
- PNMA8A | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765826328, COSV58136636; called by muse, mutect2, varscan2
- PNPLA6 | c.883C>T p.R295C (on ENST00000414982 / NM_001166111.2; = p.R247C on NM_006702.5) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1057094403, COSV99654408; called by muse, mutect2, varscan2
- PORCN | c.1093C>T p.R365W (on ENST00000326194 / NM_203475.3; = p.R354W on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs398124616, CM073268, CM1210993, COSV100400507, COSV58226160; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP1R15A | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs778047173, COSV99566244; called by muse, mutect2, varscan2
- PPP1R9A | c.2630G>A p.R877H | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs372820941, COSV56896859, COSV99198442; called by muse, mutect2, varscan2
- PPP2R1B | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs564797917, COSV100232364, COSV59536410; called by muse, mutect2, varscan2
- PPP2R2C | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 115/284 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100067351, COSV58674619; called by muse, mutect2, varscan2
- PPP2R5B | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 69/142 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs141499148; called by muse, mutect2, varscan2
- PRDM5 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 111/257 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs781215728, COSV99309559; called by muse, mutect2, varscan2
- PRKG2 | c.628+1G>T p.X210_splice | Splice Site (SNP) | VAF 53/183 reads (29%) | catalogued as COSV100020440; called by muse, mutect2, varscan2
- PROM2 | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.51); PolyPhen benign (0.066); catalogued as rs752468517; called by mutect2, varscan2
- PRPF6 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1261847848, COSV53869661, COSV53874434; called by muse, mutect2, varscan2
- PRRC2A | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.463); catalogued as rs141801298; called by muse, mutect2, varscan2
- PRSS12 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 108/291 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.129); catalogued as rs201656858, COSV56604801; called by muse, mutect2, varscan2
- PRSS58 | c.256A>G p.K86E | Missense Mutation (SNP) | VAF 75/346 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV101616161; called by muse, mutect2, varscan2
- PSD3 | c.2428C>T p.R810* (on ENST00000440756; = p.R809* on NM_015310.4) | Nonsense Mutation (SNP) | VAF 80/188 reads (43%) | catalogued as COSV99676754; called by muse, mutect2, varscan2
- PSMC2 | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 34/177 reads (19%) | catalogued as COSV99485433; called by muse, mutect2, varscan2
- PSME2 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1136581, COSV99395531; called by muse, mutect2, varscan2
- PTCH1 | c.3391G>A p.V1131M | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as rs566619057, COSV59470630; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTER | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as rs767621618, COSV100126821, COSV100126834, COSV100126861; called by muse, mutect2, varscan2
- PTGER2 | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 46/137 reads (34%) | catalogued as rs774899041, COSV99817715; called by muse, mutect2, varscan2
- PTGER4 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as rs1182102115, COSV100201732; called by muse, mutect2, varscan2
- PTPN3 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.851); catalogued as rs200472346, COSV52704856; called by muse, mutect2, varscan2
- PTPRN2 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs199560003, COSV67060709; called by muse, mutect2, varscan2
- PTPRS | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.104); catalogued as rs73545312; called by muse, mutect2, varscan2
- PUM1 | c.2026G>A p.G676R | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370113450; called by muse, mutect2, varscan2
- QTRT1 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 99/202 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746933825, COSV51551622; called by muse, mutect2, varscan2
- RABGGTA | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs1366113873, COSV99397784, COSV99397866; called by muse, mutect2, varscan2
- RANBP10 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs758630219, COSV58157678, COSV58157767; called by muse, mutect2, varscan2
- RAPGEF2 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 92/225 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.511); catalogued as rs754181086, COSV52427555; called by muse, mutect2, varscan2
- RASAL1 | c.1751C>T p.T584M | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as rs149732792; called by muse, mutect2, varscan2
- RASGRF2 | c.2768G>A p.R923H | Missense Mutation (SNP) | VAF 104/216 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54134589, COSV99430118; called by muse, mutect2, varscan2
- RASGRP4 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs181501556; called by muse, mutect2, varscan2
- RB1CC1 | c.3463T>A p.L1155I | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV99212787; called by muse, mutect2, varscan2
- RBBP6 | c.3758G>A p.R1253Q | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.493); catalogued as rs1032305860, COSV60506750; called by muse, mutect2, varscan2
- RBM10 | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.775); catalogued as COSV99333361; called by muse, mutect2, varscan2
- RBM19 | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754522463, COSV55701248; called by muse, mutect2, varscan2
- RBM23 | c.865-2A>G p.X289_splice (on ENST00000359890 / NM_001077351.2; = p.X273_splice on NM_018107.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 29/93 reads (31%) | catalogued as COSV100321457, COSV100321495; called by muse, mutect2, varscan2
- RBP3 | c.2828C>T p.T943M | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); catalogued as rs782362888; called by muse, mutect2, varscan2
- RCL1 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs1311804560, COSV101099600; called by muse, mutect2
- REL | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1352140789, COSV54365226; called by muse, varscan2
- REPS2 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 109/318 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs756540323, COSV58178704; called by muse, mutect2, varscan2
- RESF1 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.203); catalogued as COSV100440559; called by muse, mutect2, varscan2
- RGS12 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1202694533, COSV100376251; called by muse, mutect2, varscan2
- RHBDL3 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs776334303, COSV52186052, COSV52188520; called by muse, mutect2, varscan2
- RIOK2 | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 101/258 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs986347419, COSV99300135, COSV99300177; called by muse, mutect2, varscan2
- RNF213 | c.9799G>A p.V3267M | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as rs199799029, COSV100301341; called by muse, mutect2, varscan2
- RNF213 | c.14123G>A p.R4708H | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as rs773098626, COSV60389684; called by muse, mutect2, varscan2
- RNF216 | c.2491G>A p.V831M (on ENST00000425013 / NM_207116.3; = p.V888M on NM_207111.4) | Missense Mutation (SNP) | VAF 53/378 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs760106512, COSV66291403; called by muse, mutect2, varscan2
- RNF25 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 86/219 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs755062447, COSV99829184; called by muse, mutect2, varscan2
- ROBO1 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377297596; called by muse, mutect2, varscan2
- ROR2 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs375448033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RP2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 81/235 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs782127844, COSV99509295; called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.947); catalogued as COSV100402582; called by muse, mutect2, varscan2
- RPS6KL1 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.832); catalogued as rs777332209, COSV63581038, COSV63581705; called by muse, mutect2, varscan2
- RRAGB | c.1121G>A p.R374H (on ENST00000262850 / NM_016656.4; = p.R346H on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.988); catalogued as rs761824997, COSV53331095, COSV99469611; called by muse, mutect2
- RTF2 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.396); catalogued as rs149439941; called by muse, mutect2, varscan2
- RTL5 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.558); catalogued as rs768312794, COSV65454236; called by muse, mutect2, varscan2
- RUNX1T1 | c.1255G>A p.V419I (on ENST00000265814 / NM_001198628.1; = p.V392I on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/268 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as rs763084019, COSV56148701; called by muse, mutect2, varscan2
- RUNX3 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100137070; called by muse, mutect2
- RWDD2A | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as rs1174716121, COSV52283608; called by muse, mutect2, varscan2
- RXRA | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs746817210, COSV100709351, COSV99072133; called by muse, mutect2, varscan2
- RXRG | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747060865, COSV63233586; called by muse, mutect2, varscan2
- RYR1 | c.8893C>T p.R2965C | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs780682934, COSV100616791; called by muse, mutect2, varscan2
- SAFB | c.2323C>T p.R775* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as rs1439089201, COSV52651066; called by muse, mutect2, varscan2
- SAMD11 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100574702; called by muse, mutect2
- SBF1 | c.4498G>A p.G1500R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV100817993; called by muse, mutect2, varscan2
- SCN4A | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV101438629; called by muse, mutect2, varscan2
- SCN5A | c.3662C>T p.A1221V (on ENST00000333535 / NM_198056.3; = p.A1220V on NM_000335.5) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs727503407, CM121678, COSV100350242, COSV61142894; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDC1 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs78365527; called by muse, mutect2, varscan2
- SEC14L1 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 84/242 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs201160040; called by muse, mutect2, varscan2
- SEC14L2 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 24/90 reads (27%) | catalogued as rs139307031, COSV100464762; called by muse, varscan2
- SEC14L5 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750893044, COSV52037622; called by muse, mutect2, varscan2
- SECISBP2 | c.2303C>T p.A768V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as rs768165380, COSV59402400; called by muse, mutect2, varscan2
- SECTM1 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs145970176; called by muse, mutect2, varscan2
- SEMA3A | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs764858876, COSV99547814; called by muse, mutect2, varscan2
- SEMA4C | c.420C>T p.V140= | Splice Region (SNP) | VAF 25/58 reads (43%) | catalogued as rs747016420, COSV59689542; called by muse, mutect2, varscan2
- SENP6 | c.2150G>A p.R717H | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs12195603, COSV100894616; called by muse, mutect2, varscan2
- SERPINB1 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs924613628, COSV101058479; called by muse, mutect2, varscan2
- SETD7 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs200323700, COSV56799865, COSV56801210; called by muse, mutect2, varscan2
- SGSM3 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs374291042; called by muse, mutect2, varscan2
- SGSM3 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 125/362 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.148); catalogued as rs755753950, COSV99960170; called by muse, mutect2, varscan2
- SH2B1 | c.1589G>A p.G530E | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100451226; called by muse, mutect2, varscan2
- SH3YL1 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs777401493, COSV62155887; called by muse, mutect2, varscan2
- SIGLEC5 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs1246078412, COSV99707849; called by muse, mutect2, varscan2
- SIN3A | c.2899C>T p.R967W | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100845221; called by muse, mutect2, varscan2
- SIN3B | c.2878C>T p.R960C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs150661186; called by muse, mutect2, varscan2
- SIRPB1 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs761841404, COSV99498551; called by muse, mutect2, varscan2
- SKI | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs747693633, COSV101049571; ClinVar: uncertain significance; called by mutect2, varscan2
- SKIV2L | c.3416G>A p.R1139Q | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.017); catalogued as rs1373847630, COSV100514829; called by muse, mutect2, varscan2
- SLC11A1 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs367760213; called by muse, mutect2, varscan2
- SLC12A7 | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs748476541, COSV53757761, COSV53763561; called by muse, mutect2, varscan2
- SLC19A1 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.964); catalogued as rs770678515, COSV100229129; called by muse, mutect2, varscan2
- SLC1A2 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs780330935, COSV99554979; called by muse, mutect2, varscan2
- SLC1A6 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1301909733, COSV99694151; called by muse, mutect2, varscan2
- SLC22A14 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 107/263 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as rs146612743; called by muse, mutect2, varscan2
- SLC22A2 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs773374729, COSV100871028; called by muse, mutect2, varscan2
- SLC23A2 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568605051, COSV57772696; called by muse, mutect2, varscan2
- SLC24A3 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100042770; called by muse, mutect2, varscan2
- SLC24A4 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171307519, COSV54118684; called by muse, mutect2
- SLC25A23 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as rs779989407, COSV99902571; called by muse, mutect2, varscan2
- SLC26A9 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs867239254, COSV61601688; called by muse, mutect2, varscan2
- SLC34A3 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 83/214 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757872964, COSV100746712; called by muse, mutect2, varscan2
- SLC38A10 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs956829381, COSV55843298; called by muse, mutect2, varscan2
- SLC38A4 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs538386001, COSV99872794; called by muse, mutect2, varscan2
- SLC39A10 | c.1273G>A p.V425M | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779765683, COSV62767121, COSV62769432; called by muse, mutect2, varscan2
- SLC39A4 | c.449G>A p.R150Q (on ENST00000301305 / NM_001374839.1; = p.R125Q on NM_017767.3) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782199942, COSV99433680; called by muse, mutect2, varscan2
- SLC5A7 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs757211775, COSV50896555; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLCO1B3 | c.460T>A p.S154T | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV99682138; called by muse, mutect2, varscan2
- SLIT2 | c.3620C>T p.A1207V | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs1041546615, COSV99886780; called by muse, mutect2, varscan2
- SLPI | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as rs536988897, COSV58092410; called by muse, mutect2, varscan2
- SLU7 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.508); catalogued as rs971318091, COSV99775797; called by muse, mutect2, varscan2
- SMARCA1 | c.2587C>T p.R863* | Nonsense Mutation (SNP) | VAF 41/129 reads (32%) | catalogued as COSV64413192; called by muse, mutect2, varscan2
- SMARCA4 | c.3928G>A p.E1310K | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1398457701, COSV100759067, COSV60805272; called by muse, mutect2, varscan2
- SMPD3 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.123); catalogued as rs1355789860, COSV54715708; called by muse, mutect2, varscan2
- SOAT2 | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.116); catalogued as rs771160659, COSV56861176; called by muse, mutect2, varscan2
- SOWAHD | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.142); catalogued as COSV100673170; called by muse, mutect2, varscan2
- SP1 | c.814G>A p.V272I (on ENST00000327443 / NM_138473.3; = p.V265I on NM_003109.1) | Missense Mutation (SNP) | VAF 104/273 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV100540825; called by muse, varscan2
- SP3 | c.1928G>A p.R643H | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV100022186; called by muse, mutect2, varscan2
- SPHK1 | c.835C>T p.R279C (on ENST00000392496 / NM_001355139.2; = p.R293C on NM_021972.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs763386887, COSV100039519; called by muse, varscan2
- SPPL2B | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774679642, COSV101476115; called by muse, mutect2, varscan2
- SPTA1 | c.7253G>A p.G2418D | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as COSV100779075; called by muse, mutect2, varscan2
- SPTBN4 | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748159055, COSV100151944; called by muse, mutect2, varscan2
- SPTSSB | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs745729640, COSV63218911; called by muse, mutect2, varscan2
- SPTY2D1 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 117/355 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100311828; called by muse, mutect2, varscan2
- SRCAP | c.7249G>A p.A2417T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs773086154, COSV52670594; called by muse, mutect2, varscan2
- SRGAP1 | c.3142G>A p.V1048M | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.54); catalogued as rs146885491; called by muse, mutect2, varscan2
- SRMS | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs533446182, COSV53918921; called by muse, mutect2, varscan2
- SRRM2 | c.7075G>A p.A2359T | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs569446082, COSV51940903; called by muse, mutect2, varscan2
- SSU72P8 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs61730745, COSV66361412; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1314C>T p.D438= | Splice Region (SNP) | VAF 28/70 reads (40%) | catalogued as rs899645475, COSV50073684, COSV50075241; called by muse, mutect2, varscan2
- SULT1C2 | c.634A>G p.M212V | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV99265392; called by muse, mutect2, varscan2
- SUV39H2 | c.1049G>A p.R350H (on ENST00000354919 / NM_001193424.2; = p.R290H on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/247 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1364606801, COSV100543174; called by muse, mutect2, varscan2
- SYCP1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199737243, COSV65694390, COSV65696392; called by muse, mutect2, varscan2
- SYNE2 | c.2328A>T p.K776N | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV100648385; called by muse, mutect2, varscan2
- SYNRG | c.2843C>T p.T948M | Missense Mutation (SNP) | VAF 83/196 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); catalogued as rs200717227; called by muse, mutect2, varscan2
- SYT17 | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as rs745715909, COSV100810834; called by muse, mutect2, varscan2
- SYT6 | c.1397G>A p.R466H (on ENST00000610222 / NM_001366225.1; = p.R381H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs148168972, COSV65775747; called by muse, mutect2, varscan2
- SZT2 | c.9562C>T p.R3188W (on ENST00000634258 / NM_001365999.1; = p.R3131W on NM_015284.4) | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758178091, COSV100981329; called by muse, mutect2, varscan2
- TAP1 | c.1114C>T p.R372* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as rs1336232266, COSV100841297; called by muse, mutect2, varscan2
- TAX1BP3 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); catalogued as rs547177128, COSV50265131; called by muse, mutect2
- TBC1D1 | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.611); catalogued as COSV99792036; called by muse, mutect2
- TBC1D12 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs748325797, COSV99831748; called by muse, mutect2, varscan2
- TBC1D2 | c.2261C>T p.T754M | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs774546155, COSV100580143; called by muse, mutect2, varscan2
- TBC1D25 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65123224; called by muse, mutect2, varscan2
- TBRG4 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs570459519, COSV51832122, COSV99345602; called by muse, mutect2, varscan2
- TBXAS1 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 80/337 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs769131779, COSV54943309; called by muse, mutect2, varscan2
- TBXT | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs149220881, COSV99752864; called by muse, mutect2
- TCAF1 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100584695; called by muse, mutect2, varscan2
- TCAP | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs750796201, COSV99510763; called by muse, mutect2, varscan2
- TCF25 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as rs139981645; called by muse, mutect2, varscan2
- TCTEX1D4 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs891727844, COSV100221267; called by muse, mutect2, varscan2
- TDO2 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376756490; called by muse, mutect2, varscan2
- TECR | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs767595944, COSV99295225; called by muse, mutect2, varscan2
- TECTA | c.3095C>T p.T1032M | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs1011014786, COSV50688397; called by muse, mutect2, varscan2
- TENM1 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 101/328 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs780598761, COSV100950499, COSV100950755; called by muse, mutect2, varscan2
- TENM2 | c.7748C>T p.T2583M (on ENST00000518659 / NM_001122679.2; = p.T2344M on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs374910592; called by muse, mutect2, varscan2
- TENM3 | c.7733C>T p.T2578M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs760930126, COSV69314886; called by muse, mutect2
- TET3 | c.1810C>T p.R604* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV59880697, COSV99996537; called by muse, mutect2, varscan2
- TFAP2D | c.1025+2T>C p.X342_splice | Splice Site (SNP) | VAF 29/87 reads (33%) | catalogued as COSV99147260; called by muse, mutect2, varscan2
- TGFB1 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as rs868227563, COSV99700283; called by muse, mutect2, varscan2
- THBS2 | c.2713G>A p.V905I | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs184952882, COSV64679248; called by muse, mutect2
- THEG | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs575728371, COSV61073521; called by muse, mutect2, varscan2
- THEMIS | c.1136A>T p.K379M | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV100965531; called by muse, mutect2
- THSD4 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 78/152 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.551); catalogued as rs763087820, COSV99966822; called by muse, mutect2, varscan2
- TJAP1 | c.559C>T p.R187* (on ENST00000372445 / NM_001146016.1; = p.R177* on NM_080604.3) | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as rs1382298758, COSV52503251; called by muse, mutect2, varscan2
- TLL1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 117/393 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1433414959, COSV50342931; called by muse, mutect2, varscan2
- TLL2 | c.2576C>T p.T859M | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs186004686, COSV100780475; called by muse, mutect2, varscan2
- TLN1 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 62/196 reads (32%) | catalogued as COSV100148165; called by muse, mutect2, varscan2
- TM7SF3 | c.821C>T p.T274I | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100544993; called by muse, mutect2, varscan2
- TMC6 | c.2239C>T p.R747C | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs775954130, COSV100130026; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM109 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs758105259, COSV50002724; called by muse, mutect2, varscan2
- TMEM131 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.753); catalogued as rs766985459, COSV51776042; called by muse, mutect2, varscan2
- TMEM151A | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV59172905; called by muse, mutect2, varscan2
- TMEM159 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as rs748792597, COSV51785472, COSV51786134; called by muse, mutect2, varscan2
- TMEM217 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 112/271 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs367675539; called by muse, mutect2, varscan2
- TMEM25 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140936953; called by muse, mutect2, varscan2
- TMEM45B | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs547067888; called by muse, mutect2, varscan2
- TMEM80 | c.260G>A p.G87D (on ENST00000526170 / NM_001276274.1; = p.G149D on NM_174940.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100585697; called by muse, mutect2, varscan2
- TMEM82 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs758596437, COSV101007904; called by muse, mutect2, varscan2
- TNC | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100406172; called by muse, mutect2, varscan2
- TNFRSF25 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100557099; called by muse, mutect2
- TNIK | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs763322605, COSV52681019, COSV52691388; called by muse, mutect2, varscan2
- TNIP2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs770013204, COSV59569599; called by muse, mutect2, varscan2
- TNNC1 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs370103102, COSV99234607; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNPO3 | c.1474G>A p.V492I | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758997411, COSV55279465; called by muse, mutect2, varscan2
- TNRC6B | c.5066G>A p.R1689Q (on ENST00000454349 / NM_001162501.2; = p.R1579Q on NM_015088.3) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1369299625, COSV100110379; called by muse, mutect2, varscan2
- TNXB | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100926584; called by muse, mutect2, varscan2
- TONSL | c.2652G>A p.M884I | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV101340304; called by muse, mutect2, varscan2
- TOPBP1 | c.3346C>T p.R1116* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as COSV99605765; called by muse, mutect2, varscan2
- TP73 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.852); catalogued as rs777997255, COSV100601565; called by muse, mutect2, varscan2
- TRAPPC12 | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100160894; called by muse, varscan2
- TRERF1 | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747612556, COSV100551486; called by muse, mutect2, varscan2
- TRIM14 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.185); catalogued as rs753405523, COSV100419703, COSV58355706; called by muse, mutect2, varscan2
- TRIM23 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99139927; called by muse, mutect2
- TRIM3 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs1227346304, COSV100624529; called by muse, mutect2, varscan2
- TRIM56 | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 55/321 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758519271, COSV60159037; called by muse, mutect2, varscan2
- TRIO | c.8335C>T p.P2779S | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.035); catalogued as rs745436046, COSV100702585, COSV100702705; called by muse, mutect2, varscan2
- TRIP12 | c.2558C>T p.A853V | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs754497274, COSV99390853; called by muse, mutect2, varscan2
417 further variants in this file (67 protein-altering or splice-affecting, 333 silent, 17 other) are not listed here.
